Somatic mutation profile of tumor specimen MP2PRT-PAVXUA-TMP1-A (aliquot MP2PRT-PAVXUA-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVXUA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.7 years (2,094 days).
Specimen MP2PRT-PAVXUA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad74d6cf-bbdc-4836-b19c-aee3b00ff515.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVXUA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVXUA-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b64d84a3-f715-416d-9c6d-aaf50221f183

The open-access MAF lists 27 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 7, Intron 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.3974C>T p.T1325M | Missense Mutation (SNP) | VAF 124/409 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756414393, CM149629, COSV67979398; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HEPHL1 | c.3276C>T p.N1092= | Splice Region (SNP) | VAF 36/417 reads (9%) | catalogued as rs560509955, COSV100243839, COSV59889234; called by muse, mutect2
- KMT2C | c.1786C>T p.L596F | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.088); catalogued as COSV51422831; called by muse, mutect2
- RYR1 | c.2251G>A p.V751M | Missense Mutation (SNP) | VAF 211/494 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs767667578, COSV100614018, COSV62104732; called by muse, mutect2, varscan2
- TNXB | c.11198C>T p.T3733M (on ENST00000647633; = p.T3486M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/632 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.95); catalogued as rs368518664; called by muse, mutect2, varscan2
- BRWD3 | c.5003G>A p.R1668K | Missense Mutation (SNP) | VAF 229/604 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- C4orf54 | c.1246C>G p.P416A | Missense Mutation (SNP) | VAF 18/432 reads (4%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.911); called by muse, mutect2
- CTCF | c.1336A>G p.I446V | Missense Mutation (SNP) | VAF 32/291 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- IGKV1D-16 | chr2:90100738 TCCCACAGTGTTACAC>GCCA | Missense Mutation (DEL) | VAF 33/184 reads (18%) | called by pindel, varscan2*
- ITGB2 | c.1118C>T p.S373F (on ENST00000302347; = p.S349F on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 132/412 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- MYOM3 | c.13C>T p.H5Y | Missense Mutation (SNP) | VAF 24/374 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.14); called by muse, mutect2
- PHACTR3 | c.460C>A p.P154T | Missense Mutation (SNP) | VAF 49/465 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- PTPRM | c.2317C>T p.R773W | Missense Mutation (SNP) | VAF 144/305 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- SLCO4C1 | c.532G>T p.A178S | Missense Mutation (SNP) | VAF 18/508 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.07); called by muse, mutect2
- SYCP2L | c.565T>G p.F189V | Missense Mutation (SNP) | VAF 87/229 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UGT2A1 | c.961C>G p.L321V | Missense Mutation (SNP) | VAF 17/401 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- USP13 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 166/396 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- USP13 | c.17C>A p.A6D | Missense Mutation (SNP) | VAF 168/402 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- IGLV1-40 | c.21C>T p.L7= | Silent (SNP) | VAF 117/272 reads (43%) | catalogued as rs774746915; called by muse, mutect2, varscan2
- KCNB2 | c.531G>A p.K177= | Silent (SNP) | VAF 158/353 reads (45%) | called by muse, mutect2, varscan2
- NOD2 | c.2985C>T p.I995= | Silent (SNP) | VAF 101/195 reads (52%) | called by muse, mutect2, varscan2
- NPR1 | c.2571G>A p.V857= | Silent (SNP) | VAF 24/280 reads (9%) | called by muse, mutect2
- RPS6KA1 | c.2040G>A p.K680= | Silent (SNP) | VAF 208/479 reads (43%) | called by muse, mutect2, varscan2
- SH3BP5 | c.507G>A p.A169= | Silent (SNP) | VAF 21/289 reads (7%) | catalogued as rs557635631, COSV53744254; called by muse, mutect2
- SYCP2L | c.564T>C p.T188= | Silent (SNP) | VAF 87/230 reads (38%) | catalogued as COSV51658222; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73825597 T>A | 5'Flank (SNP) | VAF 37/281 reads (13%) | called by muse, mutect2, varscan2
- OBSCN | c.5138-1677C>T | Intron (SNP) | VAF 66/670 reads (10%) | catalogued as COSV99483989; called by muse, mutect2
